Somatic mutation profile of tumor specimen C3L-02602-02 (aliquot CPT0113910009) from CPTAC case C3L-02602, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.1 years (20,872 days).
Specimen C3L-02602-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df746289-45a3-4574-b236-506dc5cdbcfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02602-31 (Blood Derived Normal), aliquot CPT0115300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/297a436a-3f14-4b35-80de-4ad57c11319e

The open-access MAF lists 1,081 somatic variants for this specimen: 735 protein-altering or splice-affecting, 211 silent, 135 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 494, Silent 211, Frame Shift Del 153, Intron 70, Frame Shift Ins 39, 3'UTR 25, 5'UTR 20, Nonsense Mutation 20, Splice Site 18, RNA 8, Splice Region 6, 5'Flank 6.

Variants (750 of 1,081; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 62/146 reads (42%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 95/258 reads (37%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 256/590 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 101/356 reads (28%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 78/230 reads (34%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAPK1 | c.965A>C p.E322A | Missense Mutation (SNP) | VAF 62/132 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53186801, COSV53187017; called by muse, mutect2, varscan2
- MSH6 | c.3312del p.F1104Lfs*11 | Frame Shift Del (DEL) | VAF 94/376 reads (25%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1034A>C p.N345T | Missense Mutation (SNP) | VAF 36/55 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1057519938, COSV55881772, COSV55902438, COSV55902706; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 67/78 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel
- ABCA2 | c.3934G>A p.E1312K (on ENST00000614293; = p.E1282K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.726); catalogued as rs764897224, COSV55799388, COSV99688272; called by muse, mutect2, varscan2
- ABCA5 | c.2930T>C p.V977A | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1295674293, COSV67019119; called by muse, mutect2, varscan2
- ABCB11 | c.3371A>G p.Q1124R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779530257; called by mutect2, varscan2
- ABCC5 | c.2564del p.G855Afs*14 | Frame Shift Del (DEL) | VAF 87/386 reads (23%) | catalogued as rs1158884698; called by mutect2, pindel, varscan2
- ABL2 | c.1535del p.P512Lfs*7 (on ENST00000502732 / NM_007314.4; = p.P497Lfs*7 on NM_005158.5) | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | catalogued as rs753365868, COSV61019281; called by pindel, varscan2
- ACAD10 | c.2393A>G p.Q798R | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as rs1239431516; called by muse, mutect2, varscan2
- ACOT11 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 153/384 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs760940427; called by muse, mutect2, varscan2
- ACSM2B | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs771347362; called by muse, mutect2, varscan2
- ACTN1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV51998200; called by muse, mutect2, varscan2
- ADAM8 | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs367803725; called by muse, mutect2, varscan2
- ADARB1 | c.1775A>G p.H592R (on ENST00000360697 / NM_001346687.2; = p.H552R on NM_001112.4) | Missense Mutation (SNP) | VAF 26/401 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV62342138, COSV62344645; called by muse, mutect2
- ADCY6 | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 175/422 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.871); catalogued as rs769901417; called by muse, mutect2, varscan2
- AF196969.1 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 180/502 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as rs782736490, COSV52141568; called by muse, varscan2
- AHNAK | c.16919T>C p.L5640P | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs143067494; called by muse, mutect2, varscan2
- ANK3 | c.12414A>T p.L4138F (on ENST00000280772 / NM_001320874.2; = p.L659F on NM_001149.3) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55049756; called by muse, mutect2, varscan2
- ANK3 | c.2984del p.G995Afs*3 (on ENST00000280772 / NM_001320874.2; = p.G129Afs*3 on NM_001149.3) | Frame Shift Del (DEL) | VAF 110/385 reads (29%) | catalogued as rs1064796890; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- AP1M2 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs370653364; called by muse, mutect2, varscan2
- APBB3 | c.376T>C p.W126R | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750323334; called by muse, mutect2, varscan2
- AQP7 | c.189del p.K63Nfs*31 | Frame Shift Del (DEL) | VAF 71/193 reads (37%) | catalogued as COSV53008175; called by mutect2, varscan2
- AR | c.2462G>T p.G821V | Missense Mutation (SNP) | VAF 135/349 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM983651, COSV101018445; called by muse, mutect2, varscan2
- ARFGEF3 | c.1064del p.P355Hfs*11 | Frame Shift Del (DEL) | VAF 42/153 reads (27%) | catalogued as rs147530147; called by mutect2, varscan2
- ARHGEF12 | c.4153C>T p.R1385C | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs750431916, COSV63107583; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 66/158 reads (42%) | catalogued as rs753865255; called by mutect2, varscan2
- ASH1L | c.3673C>T p.H1225Y | Missense Mutation (SNP) | VAF 68/323 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.346); catalogued as COSV64210082; called by muse, mutect2, varscan2
- ASTN1 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 90/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770355300; called by muse, mutect2, varscan2
- ATM | c.8620C>T p.Q2874* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as CM031645; called by muse, mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- BAIAP3 | c.2437G>A p.V813M | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs754353782, COSV50105287; called by mutect2, varscan2
- BCAT2 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201958057; called by muse, mutect2, varscan2
- BCORL1 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 132/345 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748283467, COSV54394956; called by muse, mutect2, varscan2
- BCR | c.2332del p.L778Wfs*10 | Frame Shift Del (DEL) | VAF 74/243 reads (30%) | catalogued as COSV100007045; called by mutect2, pindel, varscan2
- BICD2 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 29/624 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs1192666081; called by muse, mutect2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 29/95 reads (31%) | catalogued as rs755506199; called by mutect2, varscan2
- BIRC6 | c.11426G>A p.R3809Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs371563925; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 33/155 reads (21%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRD4 | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 179/441 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1257481812; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 109/300 reads (36%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BUB1 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as rs780060793, COSV57067707; called by muse, mutect2, varscan2
- C10orf71 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 116/490 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100110414, COSV60505553; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 37/133 reads (28%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C5AR1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as rs1415152795, COSV100754060; called by muse, mutect2, varscan2
- C6 | c.2131del p.E711Kfs*3 | Frame Shift Del (DEL) | VAF 77/246 reads (31%) | catalogued as COSV99666836, COSV99666909; called by mutect2, pindel, varscan2
- C6orf47 | c.482A>G p.E161G | Missense Mutation (SNP) | VAF 144/351 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs76967027; called by muse, varscan2
- CACNA1A | c.7335del p.V2446Yfs*168 (on ENST00000614285; = p.V2446Yfs*? on NM_023035.3) | Frame Shift Del (DEL) | VAF 68/196 reads (35%) | catalogued as rs1214586505, COSV64200082; called by mutect2, pindel, varscan2
- CACNA1A | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 143/410 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV64190796; called by muse, mutect2, varscan2
- CACNA1E | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 155/789 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1161110769, COSV100702987; called by muse, mutect2, varscan2
- CACNA1S | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 128/793 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs753901380, COSV62941976; called by muse, mutect2, varscan2
- CARD14 | c.1437del p.S480Afs*49 | Frame Shift Del (DEL) | VAF 101/261 reads (39%) | catalogued as rs780143594; called by mutect2, pindel, varscan2
- CARS2 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs138372705; called by muse, mutect2, varscan2
- CASP8AP2 | c.3390del p.K1130Nfs*6 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as rs768812342; called by mutect2, varscan2
- CCDC50 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776014358, COSV66667353; called by muse, mutect2, varscan2
- CCDC87 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs767088192; called by muse, mutect2, varscan2
- CCNF | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.642); catalogued as rs140456910; called by muse, mutect2, varscan2
- CD1D | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs529047977, COSV100939571, COSV63808905; called by muse, mutect2, varscan2
- CDH16 | c.2140C>T p.R714W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746385233; called by muse, mutect2, varscan2
- CDH8 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.99); catalogued as COSV54872322; called by muse, mutect2, varscan2
- CDIP1 | c.290del p.P97Qfs*29 | Frame Shift Del (DEL) | VAF 104/310 reads (34%) | catalogued as COSV99566739; called by mutect2, pindel, varscan2
- CDK12 | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1367487092; called by muse, mutect2, varscan2
- CEP164 | c.3725G>A p.R1242H | Missense Mutation (SNP) | VAF 100/204 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.094); catalogued as rs775665636, COSV54044727; called by muse, mutect2, varscan2
- CEP350 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs568579774, COSV100854674; called by muse, mutect2, varscan2
- CERCAM | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1431383945; called by muse, mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs1274191949; called by mutect2, varscan2
- CHI3L1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs112567571; called by muse, mutect2, varscan2
- CNBP | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 83/283 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69654364; called by muse, mutect2, varscan2
- CNOT3 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs1232022938, COSV99652084; called by muse, mutect2, varscan2
- COBL | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 119/333 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781148295, COSV99471563; called by muse, mutect2, varscan2
- COL1A1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs781774588; called by muse, mutect2, varscan2
- COL24A1 | c.3353del p.K1118Rfs*7 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs1170230275; called by mutect2, pindel, varscan2
- CORIN | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as rs1360158986; called by muse, mutect2, varscan2
- COTL1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.974); catalogued as rs753995579, COSV52290330; called by muse, mutect2, varscan2
- CPNE2 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs775368038; called by muse, mutect2, varscan2
- CRACR2B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs773138241; called by muse, mutect2, varscan2
- CROCC | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs545352105; called by muse, mutect2, varscan2
- CSMD3 | c.2681C>T p.P894L (on ENST00000297405 / NM_001363185.1; = p.P790L on NM_052900.3) | Missense Mutation (SNP) | VAF 131/241 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs779301839, COSV52227467; called by muse, mutect2, varscan2
- CYP11B1 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 215/916 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs781052848, COSV99455178; called by muse, mutect2, varscan2
- CYP17A1 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 148/564 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as HM080104; called by muse, mutect2, varscan2
- DEFB127 | c.196dup p.I66Nfs*50 | Frame Shift Ins (INS) | VAF 38/90 reads (42%) | catalogued as rs1375522756; called by mutect2, varscan2
- DENND4B | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs763977421; called by muse, mutect2, varscan2
- DHRS13 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 141/345 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs201593315, COSV66683835; called by muse, mutect2, varscan2
- DHX9 | c.2560A>G p.I854V | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1438406750; called by muse, mutect2, varscan2
- DISP1 | c.3444del p.K1148Nfs*26 | Frame Shift Del (DEL) | VAF 96/545 reads (18%) | catalogued as rs1478802964; called by mutect2, pindel, varscan2
- DMXL2 | c.326del p.L109* | Frame Shift Del (DEL) | VAF 36/80 reads (45%) | catalogued as rs752363479; called by mutect2, varscan2
- DNAH12 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs759126410, COSV61060890; called by muse, mutect2, varscan2
- DNAH14 | c.10489C>T p.R3497W (on ENST00000445597; = p.R4505W on NM_001367479.1) | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs554918900, COSV99687157; called by muse, mutect2, varscan2
- DNAH5 | c.10192C>T p.R3398C | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs147882360; ClinVar: uncertain significance; called by muse, mutect2
- DNAH9 | c.5935C>T p.R1979C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202048857, COSV52357769; called by muse, mutect2, varscan2
- DNAI1 | c.771del p.K257Nfs*7 | Frame Shift Del (DEL) | VAF 134/326 reads (41%) | catalogued as COSV54284836; called by mutect2, varscan2
- DNMBP | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 210/722 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs530209398; called by muse, mutect2, varscan2
- DOCK1 | c.3749C>T p.S1250L | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs1055960911, COSV54732628; called by muse, mutect2
- DOCK5 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs776762641; called by muse, mutect2, varscan2
- DOK6 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1203760352; called by muse, mutect2, varscan2
- DSEL | c.3242G>A p.C1081Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1232006924, COSV100025269; called by muse, mutect2, varscan2
- DTL | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs780485662; called by muse, mutect2, varscan2
- ECEL1 | c.1700del p.P567Hfs*48 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | catalogued as COSV58813737; called by mutect2, varscan2
- EEF1AKNMT | c.842G>A p.R281H (on ENST00000361735 / NM_015935.5; = p.R195H on NM_014955.3) | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs371406091, COSV100675745; called by muse, mutect2, varscan2
- EFCAB7 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs372824134; called by muse, mutect2, varscan2
- EIF2A | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1385275914; called by muse, mutect2, varscan2
- EIF4G1 | c.2636G>A p.R879H (on ENST00000346169 / NM_198241.3; = p.R684H on NM_004953.5) | Missense Mutation (SNP) | VAF 120/454 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs1199797589, COSV59994054; called by muse, mutect2, varscan2
- ELAPOR2 | c.799G>A p.G267S (on ENST00000450689 / NM_001142749.3; = p.G100S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.749); catalogued as rs368712643; called by muse, mutect2, varscan2
- ESRRB | c.1447dup p.L483Pfs*3 | Frame Shift Ins (INS) | VAF 88/284 reads (31%) | catalogued as rs1375524514; called by mutect2, pindel
- ETS1 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.668); catalogued as rs375860265, COSV100090851; called by muse, mutect2, varscan2
- EVI5 | c.648del p.F216Lfs*15 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as rs1453325274; called by mutect2, pindel, varscan2
- F11 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 119/312 reads (38%) | catalogued as rs281875279, CM990520; called by muse, mutect2, varscan2
- FAM131C | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866927651; called by muse, mutect2, varscan2
- FAM161A | c.1652del p.K551Rfs*26 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | catalogued as rs773807649; called by mutect2, pindel, varscan2
- FASLG | c.422del p.K141Rfs*3 | Frame Shift Del (DEL) | VAF 108/521 reads (21%) | catalogued as rs35774809; called by mutect2, varscan2
- FASTK | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 138/350 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs1487783191, COSV52540572; called by muse, mutect2, varscan2
- FES | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 155/364 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs750047865, COSV51578282; called by muse, mutect2, varscan2
- FMNL3 | c.1970C>T p.S657L | Missense Mutation (SNP) | VAF 194/430 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs1302304982; called by muse, mutect2, varscan2
- FNDC3B | c.3137C>T p.T1046I | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.235); catalogued as rs142006910; called by muse, mutect2, varscan2
- FOS | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs575850676; called by muse, mutect2, varscan2
- FOXI2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59094542, COSV99064310; called by muse, mutect2, varscan2
- FOXO4 | c.1133del p.P378Lfs*6 | Frame Shift Del (DEL) | VAF 159/477 reads (33%) | catalogued as COSV58574777; called by mutect2, pindel, varscan2
- FOXP1 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 140/560 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV59541489; called by muse, mutect2, varscan2
- FRMPD2 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs1174193623; called by muse, mutect2, varscan2
- FZD1 | c.794dup p.A266Rfs*36 | Frame Shift Ins (INS) | VAF 23/81 reads (28%) | catalogued as rs778939413; called by mutect2, pindel, varscan2
- GAB4 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775701155; called by muse, mutect2
- GIT1 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.511); catalogued as rs745617920; called by muse, varscan2
- GLOD5 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 107/246 reads (43%) | catalogued as rs782200472, COSV57489108; called by muse, mutect2, varscan2
- GOLGA6B | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs1455195982; called by mutect2, varscan2
- GPCPD1 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.91); catalogued as COSV66831222; called by muse, mutect2, varscan2
- GPR20 | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 169/619 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs766191335; called by muse, mutect2, varscan2
- GRM1 | c.792C>A p.N264K | Missense Mutation (SNP) | VAF 231/574 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51111790; called by muse, mutect2, varscan2
- GRM6 | c.1468G>T p.V490L | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV51449828; called by muse, mutect2, varscan2
- GRM7 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 103/285 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1184581533, COSV63139483, COSV63174119; called by muse, mutect2, varscan2
- GSE1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 280/662 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs933686551, COSV53673358; called by muse, mutect2, varscan2
- GTPBP6 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 132/356 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.79); catalogued as rs774724744, COSV100397775; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | catalogued as COSV54945907; called by mutect2, varscan2
- HDGF | c.716+3G>A | Splice Region (SNP) | VAF 21/428 reads (5%) | catalogued as rs1438437715; called by muse, mutect2
- HECTD4 | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs865930487, COSV61178769; called by muse, mutect2, varscan2
- HK2 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 210/732 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); catalogued as rs1450833900; called by muse, mutect2, varscan2
- HSD11B2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 375/885 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs546805920; called by muse, mutect2, varscan2
- IGSF3 | c.2750G>A p.S917N (on ENST00000369486 / NM_001007237.3; = p.S937N on NM_001542.4) | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100604616, COSV59597750; called by muse, mutect2, varscan2
- IGSF9 | c.2327-1G>T p.X776_splice (on ENST00000368094 / NM_001135050.2; = p.X760_splice on NM_020789.4) | Splice Site (SNP) | VAF 20/378 reads (5%) | catalogued as COSV100230905; called by muse, mutect2
- INO80 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 131/295 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs978133834, COSV62741126; called by muse, mutect2, varscan2
- INSRR | c.2188G>A p.V730M | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs777770717, COSV63871746; called by muse, mutect2
- IRX3 | c.706dup p.E236Gfs*12 | Frame Shift Ins (INS) | VAF 72/190 reads (38%) | catalogued as rs761463912; called by mutect2, varscan2
- ITGA1 | c.2069T>C p.M690T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs1166677108; called by muse, mutect2, varscan2
- ITGB1 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs1455572744, COSV56478902, COSV56482367; called by muse, mutect2, varscan2
- JAK1 | c.3301G>A p.V1101I | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV53808835; called by muse, mutect2, varscan2
- JPH4 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV62508199; called by muse, mutect2, varscan2
- JSRP1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs1420743773; called by muse, mutect2, varscan2
- KCNH1 | c.2134G>A p.D712N (on ENST00000271751 / NM_172362.3; = p.D685N on NM_002238.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1243866804, COSV55107244; called by muse, varscan2
- KCNH4 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs755522577, COSV52916535; called by muse, mutect2, varscan2
- KCNQ4 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 212/488 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61272948; called by muse, mutect2, varscan2
- KCNV1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs1157202808, COSV52084721; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 59/190 reads (31%) | catalogued as rs1339576763; called by mutect2, pindel, varscan2
- KIAA2012 | c.2523del p.K841Nfs*2 | Frame Shift Del (DEL) | VAF 75/132 reads (57%) | catalogued as rs760609491; called by mutect2, varscan2
- KIF1A | c.2600T>C p.V867A | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as rs1162550585; called by muse, mutect2, varscan2
- KIF1A | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57501589; called by muse, mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 37/121 reads (31%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KLHL40 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs376618797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL40 | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 126/482 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.142); catalogued as COSV55134140; called by muse, mutect2, varscan2
- KMT2A | c.10786G>A p.V3596M | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV63286481; called by muse, mutect2, varscan2
- KNDC1 | c.4495G>T p.G1499C | Missense Mutation (SNP) | VAF 107/454 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58841213; called by muse, mutect2, varscan2
- KRTAP5-8 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.643); catalogued as rs765981099; called by muse, mutect2
- KSR1 | c.923G>A p.R308Q (on ENST00000644974 / NM_001367810.1; = p.R171Q on NM_014238.2) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs372755273; called by muse, mutect2, varscan2
- LCA5 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs374629518; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 62/160 reads (39%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LGR5 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs145133989; called by muse, mutect2, varscan2
- LGR6 | c.1903C>T p.R635C (on ENST00000367278 / NM_001017403.1; = p.R583C on NM_021636.3) | Missense Mutation (SNP) | VAF 116/486 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs971296097; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | catalogued as rs780042765; called by mutect2, varscan2
- LRRFIP1 | c.1014G>T p.E338D (on ENST00000392000 / NM_001137552.2; = p.E314D on NM_004735.4) | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV55256243; called by muse, mutect2, varscan2
- LTBP3 | c.1843G>A p.V615M | Missense Mutation (SNP) | VAF 260/635 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV57240067, COSV57242196; called by muse, mutect2, varscan2
- LTK | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.08); catalogued as rs1199839512; called by muse, mutect2, varscan2
- MAMLD1 | c.1920C>T p.G640= | Splice Region (SNP) | VAF 162/412 reads (39%) | catalogued as rs1387943239; called by muse, mutect2, varscan2
- MAST1 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 139/323 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV52240349; called by muse, mutect2, varscan2
- MBD3L4 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); catalogued as rs1215759941; called by mutect2, varscan2
- MBTPS1 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 27/392 reads (7%) | catalogued as COSV104413529; called by muse, mutect2
- MCF2L | c.313G>A p.E105K (on ENST00000375608; = p.E73K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.939); catalogued as rs1475298689, COSV100982167; called by muse, mutect2, varscan2
- MCM9 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104412718; called by muse, mutect2, varscan2
- MED12L | c.1011dup p.G338Rfs*28 | Frame Shift Ins (INS) | VAF 49/154 reads (32%) | catalogued as rs772983071; called by mutect2, varscan2
- MEN1 | c.670-5del | Splice Region (DEL) | VAF 146/409 reads (36%) | catalogued as rs772016629; ClinVar: benign / likely benign; called by mutect2, pindel, varscan2
- MET | c.4123G>A p.A1375T | Missense Mutation (SNP) | VAF 114/257 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59263718; called by muse, mutect2, varscan2
- METTL27 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs376389938; called by muse, mutect2
- MIB2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879095175; called by muse, mutect2, varscan2
- MLXIPL | c.445del p.L149Cfs*29 | Frame Shift Del (DEL) | VAF 154/412 reads (37%) | catalogued as COSV100515429; called by mutect2, varscan2
- MMP15 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199590044; called by muse, mutect2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 56/152 reads (37%) | catalogued as rs777649506, COSV53202254; called by mutect2, pindel, varscan2
- MPL | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 183/415 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as CD010110; called by muse, mutect2, varscan2
- MPP3 | c.439del p.L147Wfs*40 | Frame Shift Del (DEL) | VAF 44/116 reads (38%) | catalogued as rs773841619, COSV101263331, COSV101263375; called by mutect2, pindel, varscan2
- MPZL2 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs918429088; called by muse, mutect2
- MSLNL | c.1821del p.S610Afs*80 | Frame Shift Del (DEL) | VAF 59/155 reads (38%) | catalogued as COSV53504400, COSV53506212; called by mutect2, pindel, varscan2
- MXD3 | c.148del p.Q50Rfs*24 | Frame Shift Del (DEL) | VAF 33/87 reads (38%) | catalogued as rs866699857; called by mutect2, pindel, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 97/274 reads (35%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 194/523 reads (37%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- NAA16 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); catalogued as COSV65065099; called by muse, varscan2
- NAA30 | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV53649822; called by muse, mutect2, varscan2
- NAV3 | c.5741G>A p.R1914H (on ENST00000397909 / NM_001024383.2; = p.R1892H on NM_014903.6) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs757028730, COSV57080467; called by muse, mutect2, varscan2
- NCKAP1L | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218763304, COSV53203993; called by muse, mutect2, varscan2
- NIN | c.4673C>T p.T1558M (on ENST00000382041 / NM_182946.1; = p.T845M on NM_016350.4) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs776474311, COSV55381771; called by muse, mutect2, varscan2
- NKX3-2 | c.194dup p.A66Rfs*66 | Frame Shift Ins (INS) | VAF 81/365 reads (22%) | catalogued as rs866256378; called by mutect2, pindel, varscan2
- NLRP14 | c.23_25del p.S8del | In Frame Del (DEL) | VAF 48/144 reads (33%) | catalogued as rs771837102; called by pindel, varscan2
- NPC1L1 | c.3929C>T p.A1310V | Missense Mutation (SNP) | VAF 222/527 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.493); catalogued as rs143889287, COSV99202545; called by muse, mutect2, varscan2
- NR5A1 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.246); catalogued as rs1327061057; called by muse, mutect2, varscan2
- NRAP | c.3659C>A p.P1220H (on ENST00000359988 / NM_001322945.2; = p.P1185H on NM_006175.4) | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63492876; called by muse, mutect2, varscan2
- NRXN2 | c.2416+1G>A p.X806_splice | Splice Site (SNP) | VAF 87/214 reads (41%) | catalogued as rs750887550; called by muse, mutect2, varscan2
- NSMCE1 | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs1395085551; called by muse, mutect2, varscan2
- NT5C1B | c.1235del p.G412Efs*8 (on ENST00000359846 / NM_001199086.2; = p.G352Efs*8 on NM_033253.4) | Frame Shift Del (DEL) | VAF 58/252 reads (23%) | catalogued as COSV58399018; called by mutect2, varscan2
- NTRK3 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 144/470 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs761690006, COSV58124028; called by muse, mutect2, varscan2
- NUDT14 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs368844988, COSV59306102; called by muse, mutect2, varscan2
- NUFIP1 | c.526del p.C176Vfs*27 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as rs1566064574; called by mutect2, varscan2
- NUP210 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477802749; called by muse, mutect2, varscan2
- OBSCN | c.8020G>A p.E2674K | Missense Mutation (SNP) | VAF 185/773 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs779532490; called by muse, mutect2, varscan2
- OGT | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.17); catalogued as COSV65482512; called by muse, mutect2
- OPRPN | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.248); catalogued as rs751615843, COSV68192563; called by muse, mutect2, varscan2
- OR4D2 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 354/846 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73459775, COSV73459843; called by muse, mutect2, varscan2
- OR52B2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 132/322 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs771301186, COSV73209465; called by muse, mutect2, varscan2
- OTOG | c.8350G>A p.A2784T | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs755063271, COSV100695916; called by muse, mutect2, varscan2
- PARD6A | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.014); catalogued as rs555590208; called by muse, mutect2, varscan2
- PARP3 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 96/342 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs774210062, COSV51756050; called by muse, mutect2, varscan2
- PCDHA10 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as COSV104408294; called by muse, mutect2, varscan2
- PCDHB12 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 388/928 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53397159; called by mutect2, varscan2
- PCDHB7 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 260/1288 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1554280379, COSV50753616, COSV99177008; called by muse, mutect2, varscan2
- PCDHB9 | c.1892G>A p.S631N | Missense Mutation (SNP) | VAF 380/629 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.318); catalogued as rs782525067; called by mutect2, varscan2
- PDCD11 | c.4636_4637del p.L1546Dfs*17 | Frame Shift Del (DEL) | VAF 84/454 reads (19%) | catalogued as rs1185244871; called by pindel, varscan2
- PER2 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760519574, COSV99611779; called by muse, mutect2, varscan2
- PERM1 | c.1938del p.I647Yfs*60 | Frame Shift Del (DEL) | VAF 43/138 reads (31%) | catalogued as rs1017960343; called by mutect2, pindel, varscan2
- PGBD2 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 47/217 reads (22%) | catalogued as rs376861979; called by muse, mutect2, varscan2
- PGM1 | c.1600-2A>G p.X534_splice | Splice Site (SNP) | VAF 18/420 reads (4%) | catalogued as rs1321714522; called by muse, mutect2
- PHF8 | c.370G>A p.V124I (on ENST00000357988 / NM_001184896.1; = p.V88I on NM_015107.3) | Missense Mutation (SNP) | VAF 164/401 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199664796; called by muse, mutect2, varscan2
- PIEZO1 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 117/251 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs755174284; called by muse, mutect2, varscan2
- PIEZO2 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs1555647548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITPNM2 | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 122/345 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1358831042; called by muse, mutect2, varscan2
- PKHD1L1 | c.2387T>C p.L796P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1400220635, COSV101005029; called by muse, mutect2
- PLK5 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as rs1012935214; called by muse, mutect2
- PLOD2 | c.1593G>A p.W531* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99283390; called by muse, mutect2, varscan2
- PLOD3 | c.876del p.Q293Sfs*65 | Frame Shift Del (DEL) | VAF 45/123 reads (37%) | catalogued as rs746342377, COSV56183473; called by pindel, varscan2
- PLPP2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 112/283 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs776672136; called by muse, mutect2, varscan2
- PLS3 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1556641942, COSV56780122; called by muse, mutect2, varscan2
- PLXNA1 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 169/613 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV52531121; called by muse, mutect2, varscan2
- PLXNA2 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049849429, COSV65437315; called by muse, mutect2, varscan2
- PNCK | c.633dup p.F212Lfs*8 (on ENST00000340888 / NM_001366975.1; = p.F295Lfs*8 on NM_001039582.3) | Frame Shift Ins (INS) | VAF 61/184 reads (33%) | catalogued as rs781891121; called by mutect2, varscan2
- PNPLA2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 151/417 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs761088720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POGK | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 106/662 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs752253527, COSV63311164; called by muse, mutect2, varscan2
- POLH | c.1979A>G p.Q660R | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1045727518; called by muse, mutect2, varscan2
- PON2 | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99749672; called by muse, mutect2, varscan2
- PPFIA2 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs554304662, COSV61020463; called by muse, mutect2, varscan2
- PPIAL4G | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 199/696 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs782231038; called by muse, mutect2, varscan2
- PPP1R16A | c.1333del p.H445Tfs*15 | Frame Shift Del (DEL) | VAF 44/203 reads (22%) | catalogued as rs777096925; called by mutect2, pindel, varscan2
- PPP1R3F | c.1257del p.S420Pfs*53 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs1557121351; called by mutect2, pindel, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs758484975; called by mutect2, varscan2
- PRKAR1B | c.260dup p.N88Efs*56 | Frame Shift Ins (INS) | VAF 72/200 reads (36%) | catalogued as rs764069617; called by mutect2, varscan2
- PRKCQ | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1231902533, COSV54110990; called by muse, mutect2, varscan2
- PRLHR | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 134/466 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs776987466, COSV99493053; called by muse, mutect2, varscan2
- PSEN1 | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.654); catalogued as rs138871096, COSV99998218; called by muse, mutect2, varscan2
- PTPDC1 | c.2027del p.L676Yfs*2 (on ENST00000375360 / NM_177995.3; = p.L728Yfs*2 on NM_152422.4) | Frame Shift Del (DEL) | VAF 36/108 reads (33%) | catalogued as COSV56622149; called by pindel, varscan2
- RASAL2 | c.722dup p.D242Gfs*4 | Frame Shift Ins (INS) | VAF 36/184 reads (20%) | catalogued as rs771909008; called by mutect2, varscan2
- RBFOX3 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1462993239; called by muse, mutect2, varscan2
- RCN3 | c.118del p.L40* | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | catalogued as rs777037697; called by mutect2, varscan2
- RGS3 | c.995G>T p.R332L (on ENST00000350696 / NM_001282923.2; = p.R220L on NM_017790.4) | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.9); catalogued as rs762285320; called by muse, mutect2, varscan2
- RHD | c.784del p.Q262Kfs*26 | Frame Shift Del (DEL) | VAF 182/507 reads (36%) | catalogued as COSV59646479; called by mutect2, pindel, varscan2
- RPL31 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs763221292; called by muse, mutect2, varscan2
- RPN2 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 246/631 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553588511; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 25/59 reads (42%) | catalogued as rs759252078; called by mutect2, varscan2
- S100A11 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs746862693; called by muse, mutect2, varscan2
- SART1 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 160/319 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs753645237, COSV56713394; called by muse, mutect2, varscan2
- SBF1 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1171644927, COSV62370317; called by muse, mutect2, varscan2
- SCNN1G | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 177/386 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as rs763601481, COSV55599559; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SCRIB | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs751004648; called by muse, mutect2, varscan2
- SCUBE1 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 219/495 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779618810, COSV62610335; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 58/168 reads (35%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC61G | c.197+2T>C p.X66_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV61856183; called by muse, varscan2
- SEMA3G | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51596614; called by muse, mutect2, varscan2
- SERPINB12 | c.449dup p.N150Kfs*3 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs760486497; called by mutect2, varscan2
- SERPINB3 | c.207del p.A70Lfs*20 | Frame Shift Del (DEL) | VAF 74/163 reads (45%) | catalogued as rs767073867; called by mutect2, varscan2
- SGK1 | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1343173967; called by muse, mutect2, varscan2
- SGSM1 | c.2447G>A p.S816N (on ENST00000400359 / NM_001039948.4; = p.S755N on NM_133454.3) | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as rs751660057; called by muse, mutect2, varscan2
- SH2B1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1319302640; called by muse, mutect2, varscan2
- SH2B3 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 125/331 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs746394261; called by muse, mutect2, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 44/229 reads (19%) | catalogued as rs746556543; called by mutect2, varscan2
- SIKE1 | c.418A>G p.S140G | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs977192715; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 68/174 reads (39%) | catalogued as rs767964038; called by mutect2, varscan2
- SLC28A2 | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs1237053799; called by muse, mutect2, varscan2
- SLC34A2 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 106/239 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs538449848, COSV65941877; called by muse, mutect2, varscan2
- SLC35A3 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753997682, COSV64516037; called by muse, varscan2
- SLC45A3 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751827612; called by muse, mutect2, varscan2
- SLC6A18 | c.1195del p.A399Lfs*46 | Frame Shift Del (DEL) | VAF 91/277 reads (33%) | catalogued as COSV57249716, COSV57250477; called by mutect2, pindel, varscan2
- SLC7A1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV66329630; called by muse, mutect2, varscan2
- SLC7A6 | c.1526del p.K509Rfs*26 | Frame Shift Del (DEL) | VAF 43/134 reads (32%) | catalogued as rs772028138; called by mutect2, pindel, varscan2
- SLIT1 | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 118/398 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs369984592, COSV99820732; called by muse, mutect2, varscan2
- SLITRK3 | c.2682del p.C895Afs*16 | Frame Shift Del (DEL) | VAF 43/173 reads (25%) | catalogued as COSV99578562; called by mutect2, pindel, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | catalogued as rs1466680694; called by pindel, varscan2
- SMO | c.349dup p.R117Pfs*19 | Frame Shift Ins (INS) | VAF 63/204 reads (31%) | catalogued as rs1248200595; called by mutect2, pindel, varscan2
- SMTN | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.195); catalogued as rs777851029, COSV60777617; called by muse, mutect2, varscan2
- SNX31 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 166/530 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs760972571; called by muse, mutect2, varscan2
- SNX33 | c.1299del p.C435Afs*62 | Frame Shift Del (DEL) | VAF 64/149 reads (43%) | catalogued as rs747082791; called by mutect2, pindel, varscan2
- SPG7 | c.2170G>A p.A724T (on ENST00000268704; = p.A731T on NM_003119.4) | Missense Mutation (SNP) | VAF 177/458 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs747521455, CM081824; called by muse, mutect2, varscan2
- SPHKAP | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV60870040; called by muse, mutect2
- SPINK9 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as rs1306570538; called by muse, mutect2
- SPTBN4 | c.5978C>T p.A1993V | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs765019377, COSV58948089; called by muse, mutect2, varscan2
- SSC4D | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.406); catalogued as rs751627418; called by muse, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs753462162; called by mutect2, varscan2
- SYDE1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376420111; called by muse, mutect2, varscan2
- SYT16 | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 135/320 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV101413536; called by muse, mutect2, varscan2
- TBL3 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs779874148, COSV60341632; called by muse, mutect2, varscan2
- TCHH | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 107/579 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as rs774711129; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 68/179 reads (38%) | catalogued as rs763321097; called by mutect2, varscan2
- TECPR2 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 24/371 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63968886; called by muse, mutect2
- TENM3 | c.2082dup p.T695Dfs*5 | Frame Shift Ins (INS) | VAF 71/162 reads (44%) | catalogued as rs758217137; called by mutect2, varscan2
- TES | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 168/552 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs778344836; called by muse, mutect2, varscan2
- TET1 | c.5470A>G p.S1824G | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65381941; called by muse, mutect2, varscan2
- TEX15 | c.3018del p.A1007Lfs*12 (on ENST00000256246; = p.A1390Lfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs753315680; called by mutect2, pindel, varscan2
- THSD4 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366454551; called by muse, mutect2, varscan2
- THSD7B | c.3661C>T p.P1221S (on ENST00000272643; = p.P1219S on NM_001316349.2) | Missense Mutation (SNP) | VAF 95/332 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as COSV99741990; called by muse, mutect2, varscan2
- TM4SF20 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1560003449; called by muse, mutect2, varscan2
- TM7SF3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1318715501; called by muse, mutect2, varscan2
- TMA16 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 73/159 reads (46%) | catalogued as rs746239741; called by muse, mutect2, varscan2
- TMEM127 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 177/620 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs759138897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM145 | c.76dup p.R26Pfs*40 | Frame Shift Ins (INS) | VAF 30/85 reads (35%) | catalogued as rs1245316407; called by mutect2, varscan2
- TMEM184C | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as rs1056026965; called by muse, mutect2
- TMEM187 | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 247/588 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV64141223; called by muse, mutect2, varscan2
- TMEM198 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 31/848 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.559); catalogued as rs1360776854; called by muse, mutect2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 88/118 reads (75%) | catalogued as rs747222326; called by mutect2, varscan2
- TNXB | c.7549C>T p.R2517C (on ENST00000647633; = p.R2270C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1454433703; called by muse, mutect2, varscan2
- TRA2B | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 78/276 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.375); catalogued as rs758758553, COSV52025312; called by muse, mutect2, varscan2
- TRANK1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs1318098355; called by muse, mutect2, varscan2
- TREH | c.542T>C p.M181T | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs372886649; called by muse, mutect2
- TRERF1 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 129/296 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1561875915, COSV100550485; called by muse, mutect2, varscan2
- TRPM6 | c.5747G>A p.R1916Q | Missense Mutation (SNP) | VAF 21/437 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs759362850, COSV62517785; called by muse, mutect2
- TSGA10IP | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1233418925, COSV73245335; called by muse, mutect2
- TTC13 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs139166694; called by muse, mutect2, varscan2
- TTC28 | c.5281C>T p.R1761C | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs545896036; called by muse, mutect2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs756650873; called by mutect2, varscan2
- TUB | c.1463C>T p.A488V (on ENST00000299506 / NM_177972.3; = p.A543V on NM_003320.4) | Missense Mutation (SNP) | VAF 118/321 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs1179437940; called by muse, mutect2, varscan2
- UBE3C | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1178873205, COSV61955854; called by muse, mutect2, varscan2
- UBR7 | c.1243A>G p.R415G | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.412); catalogued as rs1280350519; called by muse, mutect2, varscan2
- UMODL1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs759890870; called by muse, mutect2, varscan2
- UNC80 | c.4069C>T p.R1357* | Nonsense Mutation (SNP) | VAF 92/353 reads (26%) | catalogued as rs750226213, CM124530, COSV55897234; called by muse, mutect2, varscan2
- UQCRC1 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 73/418 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs376087580; called by muse, mutect2, varscan2
- USH2A | c.15281C>T p.P5094L | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs727503714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP11 | c.691C>T p.R231W (on ENST00000218348; = p.R188W on NM_001371072.1) | Missense Mutation (SNP) | VAF 107/249 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs754380001; called by muse, mutect2, varscan2
- USP17L2 | c.1150A>G p.S384G | Missense Mutation (SNP) | VAF 283/1507 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1389284735; called by muse, mutect2, varscan2
- USP26 | c.1461dup p.G488Wfs*6 | Frame Shift Ins (INS) | VAF 26/83 reads (31%) | catalogued as rs761320003; called by mutect2, varscan2
- USP35 | c.1962dup p.T655Hfs*74 | Frame Shift Ins (INS) | VAF 60/207 reads (29%) | catalogued as rs764735138; called by mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs761528888; called by mutect2, varscan2
- VARS1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 96/195 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as rs1346037848; called by muse, mutect2
- VPS13C | c.4429del p.I1477Lfs*24 (on ENST00000644861 / NM_020821.3; = p.I1434Lfs*24 on NM_017684.5) | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | catalogued as rs756149444; called by mutect2, varscan2
- VRTN | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1286146337, COSV99832498; called by muse, mutect2, varscan2
- WASF2 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71005016; called by muse, mutect2, varscan2
- WDFY4 | c.3628G>A p.A1210T | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs779518009, COSV57427164; called by muse, mutect2, varscan2
- WDR91 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370475929; called by muse, mutect2, varscan2
- WDR93 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs150773071; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 60/135 reads (44%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WWC3 | c.2687C>T p.S896L | Missense Mutation (SNP) | VAF 137/371 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs755914980, COSV66502817; called by muse, mutect2, varscan2
- XIRP2 | c.1537del p.D513Mfs*5 (on ENST00000628543; = p.D688Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 39/132 reads (30%) | catalogued as rs745648385; called by mutect2, pindel, varscan2
- XPNPEP1 | c.179T>C p.M60T | Missense Mutation (SNP) | VAF 78/392 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59170574; called by muse, mutect2, varscan2
- ZBTB47 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768343321; called by muse, mutect2, varscan2
- ZC3H12C | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.181); catalogued as rs201652254, COSV53712667; called by muse, mutect2, varscan2
- ZDHHC19 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1430006267, COSV99579610; called by muse, mutect2
- ZDHHC8 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs769592618; called by muse, mutect2
- ZKSCAN1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 133/323 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1425079153, COSV60875013; called by muse, mutect2, varscan2
- ZKSCAN3 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 201/446 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV52852893; called by muse, mutect2, varscan2
- ZNF358 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV51174178; called by muse, mutect2
- ZNF519 | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs758885474; called by muse, mutect2, varscan2
- ZNF572 | c.18dup p.L7Tfs*7 | Frame Shift Ins (INS) | VAF 16/75 reads (21%) | catalogued as rs769734933; called by mutect2, varscan2
- ZNF585A | c.278G>A p.R93H (on ENST00000292841 / NM_001288800.2; = p.R38H on NM_152655.3) | Missense Mutation (SNP) | VAF 163/366 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs374585649; called by muse, mutect2, varscan2
- ZNF623 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs911002713, COSV71697292; called by muse, mutect2
- ZNF831 | c.3073dup p.D1025Gfs*9 | Frame Shift Ins (INS) | VAF 14/33 reads (42%) | catalogued as rs775554241; called by mutect2, varscan2
- ZNF837 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as rs1441276097, COSV69893119; called by muse, mutect2
- ZSCAN18 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.96); PolyPhen benign (0.087); catalogued as rs146014063; called by muse, mutect2, varscan2
- ABCA1 | c.475T>C p.Y159H | Missense Mutation (SNP) | VAF 133/342 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB7 | c.991A>G p.N331D (on ENST00000373394 / NM_001271696.3; = p.N332D on NM_004299.6) | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ABLIM1 | c.1423dup p.Q475Pfs*9 | Frame Shift Ins (INS) | VAF 75/284 reads (26%) | called by mutect2, pindel, varscan2
- AC099489.1 | c.4718T>C p.M1573T | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACP3 | c.304-2A>G p.X102_splice | Splice Site (SNP) | VAF 71/233 reads (30%) | called by muse, mutect2, varscan2
- ACSM5 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- ADAM19 | c.2090del p.P697Lfs*8 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel
- ADAM30 | c.1826G>A p.G609D | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADCY5 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AFP | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, varscan2
- AHDC1 | c.4526C>T p.P1509L | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- AJAP1 | c.61del p.L21Sfs*8 | Frame Shift Del (DEL) | VAF 42/105 reads (40%) | called by mutect2, pindel, varscan2
- AKR7A2 | c.979T>G p.L327V | Missense Mutation (SNP) | VAF 58/820 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.51); called by muse, mutect2
- ALKBH5 | c.1185A>G p.*395Wext*15 | Nonstop Mutation (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- ALMS1 | c.12025C>T p.Q4009* | Nonsense Mutation (SNP) | VAF 120/397 reads (30%) | called by muse, mutect2, varscan2
- AMOT | c.2298G>T p.Q766H (on ENST00000371959 / NM_001113490.1; = p.Q357H on NM_133265.3) | Missense Mutation (SNP) | VAF 20/383 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.113); called by muse, mutect2
- ANKRD30B | c.963_985del p.K322Tfs*8 | Frame Shift Del (DEL) | VAF 101/325 reads (31%) | called by mutect2, pindel, varscan2
- ANXA3 | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- APBA2 | c.1936_1937del p.Q646Gfs*44 | Frame Shift Del (DEL) | VAF 178/556 reads (32%) | called by pindel, varscan2
- ARID1A | c.3524del p.P1175Hfs*5 | Frame Shift Del (DEL) | VAF 112/322 reads (35%) | called by mutect2, pindel, varscan2
- ARL13B | c.543del p.G182Afs*16 (on ENST00000394222 / NM_001174150.2; = p.G75Afs*16 on NM_144996.4) | Frame Shift Del (DEL) | VAF 38/143 reads (27%) | called by mutect2, pindel, varscan2
- ASMT | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 106/333 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ATR | c.3402del p.F1134Lfs*6 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | called by mutect2, pindel, varscan2
- BCR | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2
- BIVM-ERCC5 | c.196del p.I66Ffs*86 | Frame Shift Del (DEL) | VAF 42/135 reads (31%) | called by mutect2, pindel, varscan2
- BMPR1B | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRPF3 | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 11/285 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2
- BSN | c.10225A>G p.T3409A | Missense Mutation (SNP) | VAF 150/547 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BTBD16 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 112/464 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C12orf29 | c.313del p.W105Gfs*23 | Frame Shift Del (DEL) | VAF 39/121 reads (32%) | called by mutect2, pindel, varscan2
- C1orf189 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.269); called by muse, varscan2
- C2CD2L | c.1456A>G p.S486G | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD3 | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- C3AR1 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- C4BPA | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- C9orf50 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CACNB4 | c.54del p.T19Pfs*15 | Frame Shift Del (DEL) | VAF 20/95 reads (21%) | called by mutect2, pindel, varscan2
- CAPN15 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 123/286 reads (43%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CATSPERE | c.1241A>G p.N414S | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC166 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2
- CCDC168 | c.9015del p.F3005Lfs*18 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- CD79A | c.390del p.R131Gfs*61 | Frame Shift Del (DEL) | VAF 60/171 reads (35%) | called by mutect2, pindel, varscan2
- CDC14B | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CDK1 | c.-23T>A | Splice Region (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- CDKL1 | c.40G>T p.G14* | Nonsense Mutation (SNP) | VAF 46/134 reads (34%) | called by muse, mutect2, varscan2
- CELSR3 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CEMIP | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 29/487 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CEP170 | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 125/493 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP295 | c.1971A>C p.K657N | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CERS3 | c.770C>G p.T257R | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHPF2 | c.1864C>A p.H622N | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLMN | c.2594del p.K865Rfs*10 | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | called by mutect2, varscan2
- CLPTM1 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.021); called by muse, mutect2
- CLTC | c.2524A>T p.T842S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNTN2 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 235/1074 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN2 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- COL11A1 | c.1658G>C p.G553A | Missense Mutation (SNP) | VAF 97/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL22A1 | c.2174dup p.G726Wfs*101 | Frame Shift Ins (INS) | VAF 97/419 reads (23%) | called by mutect2, pindel, varscan2
- COL23A1 | c.1578del p.V527Wfs*41 | Frame Shift Del (DEL) | VAF 88/255 reads (35%) | called by mutect2, pindel, varscan2
- COLGALT1 | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 67/153 reads (44%) | called by muse, mutect2, varscan2
- COPS5 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CREM | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRISP3 | c.716dup p.Y240Vfs*6 (on ENST00000371159 / NM_001368123.1; = p.Y222Vfs*6 on NM_006061.4) | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | called by pindel, varscan2
- CRLF1 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CROCC2 | c.948-1G>A p.X316_splice | Splice Site (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2
- CRYBG2 | c.3604del p.H1202Tfs*8 | Frame Shift Del (DEL) | VAF 117/307 reads (38%) | called by mutect2, pindel, varscan2
- CSMD3 | c.4561del p.S1521Qfs*15 (on ENST00000297405 / NM_001363185.1; = p.S1417Qfs*15 on NM_052900.3) | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- CTH | c.725-1G>A p.X242_splice | Splice Site (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- CTNNA3 | c.785T>C p.M262T | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL1 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CXADR | c.602del p.N201Mfs*27 | Frame Shift Del (DEL) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- DAB2 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 108/265 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- DAPK2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 148/385 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCST1 | c.979C>A p.L327M | Missense Mutation (SNP) | VAF 136/639 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DDX24 | c.1519del p.S507Lfs*38 | Frame Shift Del (DEL) | VAF 112/361 reads (31%) | called by mutect2, pindel, varscan2
- DENND2A | c.1543A>G p.T515A | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.358); called by mutect2, varscan2
- DHX36 | c.2560del p.R854Efs*4 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel
- DIRAS2 | c.345del p.I116Sfs*43 | Frame Shift Del (DEL) | VAF 234/697 reads (34%) | called by mutect2, pindel, varscan2
- DLGAP1 | c.1860_1862dup p.N621dup | In Frame Ins (INS) | VAF 156/387 reads (40%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 246/446 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DNAH7 | c.3492del p.F1164Lfs*12 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by pindel, varscan2
- DOCK1 | c.4888del p.R1630Gfs*98 | Frame Shift Del (DEL) | VAF 72/322 reads (22%) | called by mutect2, pindel, varscan2
- DPYSL4 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 92/391 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DYNC2H1 | c.1195del p.I399* | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- EID2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 173/281 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2B4 | c.1352C>T p.A451V (on ENST00000347454 / NM_001034116.2; = p.A450V on NM_015636.3) | Missense Mutation (SNP) | VAF 168/729 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- EIF3C | c.888_891del p.N296Kfs*37 | Frame Shift Del (DEL) | VAF 134/902 reads (15%) | called by mutect2, varscan2
- EML6 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 18/351 reads (5%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.506); called by muse, mutect2
- EOGT | c.961C>A p.R321S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EOMES | c.579del p.G194Afs*94 | Frame Shift Del (DEL) | VAF 86/378 reads (23%) | called by mutect2, varscan2
- EP300 | c.6970del p.H2324Tfs*29 | Frame Shift Del (DEL) | VAF 60/154 reads (39%) | called by mutect2, pindel, varscan2
- EPHA5 | c.1268del p.N423Tfs*5 | Frame Shift Del (DEL) | VAF 192/527 reads (36%) | called by mutect2, pindel, varscan2
- EPHX1 | c.1232del p.K411Sfs*3 | Frame Shift Del (DEL) | VAF 274/1390 reads (20%) | called by mutect2, pindel, varscan2
- EPPK1 | c.4091del p.G1364Vfs*30 | Frame Shift Del (DEL) | VAF 129/476 reads (27%) | called by mutect2, pindel, varscan2
- EXOC3L1 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- EXTL3 | c.1166G>A p.S389N | Missense Mutation (SNP) | VAF 111/404 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- FAM161A | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 43/160 reads (27%) | called by muse, mutect2, varscan2
- FAM171A2 | c.2302C>G p.R768G | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2
- FAM53A | c.523T>C p.W175R | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FAM76B | c.287dup p.Y97Vfs*8 | Frame Shift Ins (INS) | VAF 36/97 reads (37%) | called by mutect2, varscan2
- FGD1 | c.1843-1G>A p.X615_splice | Splice Site (SNP) | VAF 104/252 reads (41%) | called by muse, mutect2, varscan2
- FLNA | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FMN1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- FOLH1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXA2 | c.953del p.G318Afs*5 (on ENST00000377115 / NM_153675.3; = p.G324Afs*5 on NM_021784.5) | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- FRAT1 | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 118/434 reads (27%) | called by muse, mutect2, varscan2
- FSHR | c.703A>G p.S235G | Missense Mutation (SNP) | VAF 162/494 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FUNDC1 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FUT8 | c.57del p.T20Pfs*6 | Frame Shift Del (DEL) | VAF 74/175 reads (42%) | called by mutect2, pindel, varscan2
- FUT8 | c.1207del p.R403Efs*12 (on ENST00000360689 / NM_001371534.1; = p.R240Efs*12 on NM_004480.4) | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- FZD6 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABARAPL2 | c.96T>G p.I32M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GAL3ST3 | c.695A>T p.E232V | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GALNT18 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 22/383 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- GAS2L2 | c.588del p.R197Gfs*18 | Frame Shift Del (DEL) | VAF 80/208 reads (38%) | called by mutect2, varscan2
- GATA2 | c.818del p.G273Dfs*53 | Frame Shift Del (DEL) | VAF 80/282 reads (28%) | called by mutect2, pindel, varscan2
- GCC2 | c.2439del p.E814Rfs*10 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by pindel, varscan2
- GDF1 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GDF2 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 129/544 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GLYATL3 | c.159dup p.A54Sfs*11 | Frame Shift Ins (INS) | VAF 71/192 reads (37%) | called by mutect2, pindel, varscan2
- GPR179 | c.2237G>A p.S746N (on ENST00000621958; = p.S745N on NM_001004334.4) | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- GPSM3 | c.311G>T p.R104I | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2
- GRAMD4 | c.218_219del p.E73Vfs*2 | Frame Shift Del (DEL) | VAF 72/238 reads (30%) | called by pindel, varscan2
- GREB1 | c.3459_3460insA p.Q1154Tfs*22 | Frame Shift Ins (INS) | VAF 42/160 reads (26%) | called by mutect2, pindel, varscan2
- GXYLT2 | c.1042T>C p.C348R | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GYG2 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 130/319 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H1-8 | c.657del p.K220Sfs*? | Frame Shift Del (DEL) | VAF 122/519 reads (24%) | called by mutect2, pindel, varscan2
- HDAC4 | c.2703del p.M902Wfs*55 | Frame Shift Del (DEL) | VAF 83/355 reads (23%) | called by mutect2, pindel, varscan2
- HEATR1 | c.2234C>G p.T745S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- HERC1 | c.4312T>C p.Y1438H | Missense Mutation (SNP) | VAF 181/466 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HERC6 | c.1190G>A p.S397N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- HES1 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- HMCN1 | c.6584dup p.N2196Kfs*6 | Frame Shift Ins (INS) | VAF 28/136 reads (21%) | called by mutect2, pindel, varscan2
- HOXC12 | c.843_845del p.F282del | In Frame Del (DEL) | VAF 36/84 reads (43%) | called by pindel, varscan2
- HPS6 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 51/1154 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- HSPG2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 230/544 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HTT | c.2288A>G p.Q763R | Missense Mutation (SNP) | VAF 124/288 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, varscan2
- IARS1 | c.2257A>G p.M753V | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNGR1 | c.1376A>G p.K459R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGF1R | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 172/388 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IL10RB | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 106/410 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- IL11 | c.559T>A p.W187R | Missense Mutation (SNP) | VAF 139/348 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INPP5A | c.347del p.N116Tfs*25 | Frame Shift Del (DEL) | VAF 36/139 reads (26%) | called by mutect2, pindel, varscan2
- IQGAP1 | c.2080T>C p.Y694H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ITIH1 | c.243dup p.A82Sfs*18 | Frame Shift Ins (INS) | VAF 98/482 reads (20%) | called by mutect2, pindel, varscan2
- JAK3 | c.1383del p.L462Cfs*3 | Frame Shift Del (DEL) | VAF 78/216 reads (36%) | called by mutect2, varscan2
- JCAD | c.1456del p.D486Mfs*44 | Frame Shift Del (DEL) | VAF 26/134 reads (19%) | called by mutect2, pindel, varscan2
- KANK2 | c.1680G>T p.Q560H (on ENST00000586659 / NM_001379562.1; = p.Q568H on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- KCNG3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 143/554 reads (26%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNK3 | c.827del p.G276Vfs*52 | Frame Shift Del (DEL) | VAF 81/361 reads (22%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.7911T>G p.N2637K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- KIF16B | c.1265G>A p.W422* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2
- KIF1B | c.4102T>C p.S1368P (on ENST00000377086 / NM_001365952.1; = p.S1322P on NM_015074.3) | Missense Mutation (SNP) | VAF 205/483 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- KIF4B | c.2045G>T p.R682M | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- KIFC2 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KLHL35 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 230/547 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- KLHL6 | c.1801A>C p.S601R | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- KMT2D | c.912del p.K304Nfs*30 | Frame Shift Del (DEL) | VAF 60/175 reads (34%) | called by mutect2, pindel, varscan2
- KRT24 | c.231del p.F77Lfs*79 | Frame Shift Del (DEL) | VAF 29/103 reads (28%) | called by mutect2, pindel, varscan2
- KRT74 | c.1356-2A>C p.X452_splice | Splice Site (SNP) | VAF 80/215 reads (37%) | called by muse, mutect2, varscan2
- LAT2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2
- LIG3 | c.1911+1G>A p.X637_splice | Splice Site (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- LIMS2 | c.845_847del p.S282del (on ENST00000355119 / NM_001161403.3; = p.S306del on NM_017980.4) | In Frame Del (DEL) | VAF 115/506 reads (23%) | called by mutect2, pindel, varscan2
- LINC00634 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 13/111 reads (12%) | PolyPhen benign (0.417); called by muse, mutect2, varscan2
- LONRF3 | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 153/398 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRIG1 | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LRP1 | c.12250G>A p.D4084N | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1B | c.10927G>A p.A3643T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- LRRC19 | c.888G>A p.W296* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- LRRC53 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 130/240 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- LRRTM3 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LSAMP | c.771-1G>T p.X257_splice | Splice Site (SNP) | VAF 53/202 reads (26%) | called by muse, mutect2, varscan2
- LTN1 | c.3455G>A p.G1152D | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MADCAM1 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAGEB3 | c.892del p.T298Lfs*14 | Frame Shift Del (DEL) | VAF 97/300 reads (32%) | called by mutect2, pindel, varscan2
- MAP3K14 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 111/244 reads (45%) | called by muse, mutect2, varscan2
- MCCC2 | c.1586A>G p.D529G | Missense Mutation (SNP) | VAF 113/282 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCOLN1 | c.1025T>C p.I342T | Missense Mutation (SNP) | VAF 127/327 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- MDN1 | c.5120A>G p.H1707R | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- MED12L | c.3385T>C p.C1129R | Missense Mutation (SNP) | VAF 112/565 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MEGF11 | c.1949G>T p.C650F | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- METTL21C | c.282+1dup p.X94_splice | Splice Site (INS) | VAF 22/86 reads (26%) | called by pindel, varscan2
- MEX3A | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 144/658 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MIA3 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 111/482 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MKRN1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- MON1A | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRAP | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MROH5 | c.676A>C p.M226L | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- MSH4 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTIF2 | c.1787A>G p.H596R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MTMR2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC4 | c.13705C>T p.P4569S (on ENST00000463781 / NM_018406.7; = p.P333S on NM_004532.6) | Missense Mutation (SNP) | VAF 113/462 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MUC6 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 108/327 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MYLIP | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2, varscan2
- MYOCD | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NACC2 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 177/564 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NBPF4 | c.1646A>G p.Q549R | Missense Mutation (SNP) | VAF 108/336 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCAPD3 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- NEB | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NECTIN4 | c.322del p.L108Wfs*46 | Frame Shift Del (DEL) | VAF 120/575 reads (21%) | called by mutect2, pindel, varscan2
- NEK10 | c.2668A>G p.N890D | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2
- NELFCD | c.1601C>T p.T534I (on ENST00000602795; = p.T516I on NM_198976.4) | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKD1 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NKX6-2 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NLGN1 | c.2036C>T p.T679I | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NLRP11 | c.98A>G p.K33R | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- NLRP8 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 117/298 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- NOBOX | c.1390del p.Q464Nfs*2 | Frame Shift Del (DEL) | VAF 56/154 reads (36%) | called by mutect2, varscan2
- NPAS2 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 158/539 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NPAT | c.1642del p.S548Vfs*11 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- NR3C1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 100/268 reads (37%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NR6A1 | c.1151T>G p.V384G (on ENST00000487099 / NM_033334.4; = p.V379G on NM_001489.5) | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- NRG3 | c.1412+2T>C p.X471_splice | Splice Site (SNP) | VAF 36/160 reads (23%) | called by muse, mutect2, varscan2
- NRXN3 | c.2783T>C p.I928T (on ENST00000335750 / NM_001330195.2; = p.I555T on NM_004796.6) | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- NTRK1 | c.1832T>C p.L611P | Missense Mutation (SNP) | VAF 77/385 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ODF3 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 153/362 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OFD1 | c.431del p.L144* | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- OLIG2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 166/490 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- OPA1 | c.1457C>T p.A486V (on ENST00000361510 / NM_130837.3; = p.A431V on NM_015560.3) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR1M1 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 123/268 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2S2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- OR4D11 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, varscan2
- P2RY4 | c.414C>A p.C138* | Nonsense Mutation (SNP) | VAF 70/170 reads (41%) | called by muse, mutect2, varscan2
- PABPC1L | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- PABPC4 | c.836A>T p.K279I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PACC1 | c.977T>A p.L326Q | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAMR1 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 112/277 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PBRM1 | c.4931A>C p.Q1644P (on ENST00000296302 / NM_001366071.2; = p.Q1537P on NM_018313.5) | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PCDH1 | c.2579G>A p.G860D | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH17 | c.2230A>G p.I744V | Missense Mutation (SNP) | VAF 171/400 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PDX1 | c.732del p.G245Efs*61 | Frame Shift Del (DEL) | VAF 46/126 reads (37%) | called by mutect2, pindel, varscan2
- PEAR1 | c.2865dup p.R956Qfs*33 | Frame Shift Ins (INS) | VAF 65/338 reads (19%) | called by mutect2, pindel, varscan2
- PEMT | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PERM1 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 113/246 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PI4K2B | c.692del p.K231Sfs*4 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | called by mutect2, pindel, varscan2
- PLEKHD1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 39/514 reads (8%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.616); called by muse, mutect2
- PLXND1 | c.3381del p.A1129Pfs*2 | Frame Shift Del (DEL) | VAF 100/472 reads (21%) | called by mutect2, pindel, varscan2
- POLDIP3 | c.909_910dup p.G304Vfs*14 | Frame Shift Ins (INS) | VAF 57/160 reads (36%) | called by mutect2, varscan2
- POLR1A | c.3979T>A p.Y1327N | Missense Mutation (SNP) | VAF 104/369 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPM1E | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PRDM16 | c.2862-2A>G p.X954_splice | Splice Site (SNP) | VAF 15/232 reads (6%) | called by muse, mutect2
- PRKCA | c.1139A>G p.D380G | Missense Mutation (SNP) | VAF 127/316 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRC2C | c.428A>G p.Q143R (on ENST00000367742; = p.Q141R on NM_015172.4) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PSD | c.676dup p.R226Pfs*12 | Frame Shift Ins (INS) | VAF 30/123 reads (24%) | called by mutect2, pindel, varscan2
- PSTK | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PTCD3 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PTGER3 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDN | c.2633T>C p.F878S | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RAB5A | c.163+1del | Frame Shift Del (DEL) | VAF 29/119 reads (24%) | called by mutect2, pindel, varscan2
- RBBP6 | c.4423del p.T1475Lfs*20 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- RBM33 | c.2996G>A p.G999D | Missense Mutation (SNP) | VAF 131/371 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELB | c.1436del p.P479Lfs*56 | Frame Shift Del (DEL) | VAF 87/215 reads (40%) | called by mutect2, pindel, varscan2
- RGL1 | c.1858A>G p.N620D (on ENST00000360851 / NM_001297672.2; = p.N655D on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 131/701 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RGPD2 | c.5161_5162dup p.S1721Rfs*7 | Frame Shift Ins (INS) | VAF 19/78 reads (24%) | called by mutect2, varscan2
- RIC1 | c.2863dup p.S955Kfs*2 | Frame Shift Ins (INS) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- RIMBP2 | c.2967del p.F989Lfs*14 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- RIPOR2 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RRBP1 | c.602del p.K201Rfs*72 | Frame Shift Del (DEL) | VAF 165/466 reads (35%) | called by mutect2, pindel, varscan2
- RRP8 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 100/234 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- RSAD1 | c.1291T>C p.W431R | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RTCB | c.736del p.M246Wfs*11 | Frame Shift Del (DEL) | VAF 74/254 reads (29%) | called by mutect2, pindel, varscan2
- RTL1 | c.2391A>G p.I797M | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- RTL3 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RXRB | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR3 | c.13237A>G p.R4413G (on ENST00000389232; = p.R4414G on NM_001036.6) | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAMD4B | c.1569G>T p.W523C | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SAMHD1 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SART3 | c.1610G>A p.R537K (on ENST00000228284; = p.R519K on NM_014706.4) | Missense Mutation (SNP) | VAF 194/448 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- SCD | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 208/746 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN7A | c.2105A>G p.Q702R | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCRN1 | c.1047del p.A350Pfs*19 | Frame Shift Del (DEL) | VAF 106/287 reads (37%) | called by mutect2, pindel, varscan2
- SDK1 | c.4422_4423del p.E1475Afs*48 | Frame Shift Del (DEL) | VAF 38/142 reads (27%) | called by pindel, varscan2
- SDSL | c.325del p.E109Rfs*7 | Frame Shift Del (DEL) | VAF 79/215 reads (37%) | called by mutect2, pindel, varscan2
- SEMA3B | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 68/84 reads (81%) | called by mutect2, varscan2
- SETD1B | c.4765del p.Q1589Sfs*11 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel
- SFMBT2 | c.2411C>T p.T804I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGIP1 | c.729del p.T245Lfs*23 | Frame Shift Del (DEL) | VAF 35/115 reads (30%) | called by mutect2, pindel, varscan2
- SH3BP2 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 139/283 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SH3D19 | c.803-2A>G p.X268_splice | Splice Site (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.328del p.H110Tfs*47 | Frame Shift Del (DEL) | VAF 54/201 reads (27%) | called by mutect2, pindel, varscan2
- SHANK1 | c.4823del p.P1608Rfs*17 | Frame Shift Del (DEL) | VAF 56/135 reads (41%) | called by mutect2, pindel, varscan2
- SIGLEC12 | c.1366C>T p.H456Y (on ENST00000291707 / NM_053003.4; = p.H338Y on NM_033329.2) | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- SKOR2 | c.2531A>C p.Q844P | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- SLC22A2 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SLC25A6 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 26/427 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC34A1 | c.1862del p.P621Lfs*61 | Frame Shift Del (DEL) | VAF 62/183 reads (34%) | called by mutect2, pindel, varscan2
- SLC35G2 | c.290del p.N97Tfs*10 | Frame Shift Del (DEL) | VAF 55/180 reads (31%) | called by mutect2, pindel, varscan2
- SLC9A6 | c.1464dup p.T489Yfs*23 | Frame Shift Ins (INS) | VAF 107/345 reads (31%) | called by mutect2, pindel, varscan2
- SLC9C2 | c.1617A>C p.L539F | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SLITRK3 | c.2735A>G p.E912G | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2
- SMARCC2 | c.3353G>A p.G1118E | Missense Mutation (SNP) | VAF 170/416 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SPATA1 | c.58dup p.Y20Lfs*4 | Frame Shift Ins (INS) | VAF 10/37 reads (27%) | called by mutect2, pindel
- SPG7 | c.1672A>G p.K558E (on ENST00000268704; = p.K565E on NM_003119.4) | Missense Mutation (SNP) | VAF 173/446 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SPTBN2 | c.6715G>A p.A2239T | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SRCAP | c.9299G>A p.G3100E | Missense Mutation (SNP) | VAF 104/230 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SRRM2 | c.6238G>A p.A2080T | Missense Mutation (SNP) | VAF 122/286 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- STOML1 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- SYNPR | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 118/427 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SYT15 | c.734del p.G245Afs*7 | Frame Shift Del (DEL) | VAF 18/149 reads (12%) | called by mutect2, pindel, varscan2
- SYT17 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TACC2 | c.6359C>T p.A2120V (on ENST00000334433; = p.A198V on NM_006997.4) | Missense Mutation (SNP) | VAF 158/447 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAF6 | c.1938del p.K647Sfs*58 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- TDRD10 | c.583dup p.E195Gfs*23 | Frame Shift Ins (INS) | VAF 137/750 reads (18%) | called by mutect2, pindel, varscan2
- TMA16 | c.37del p.E13Kfs*28 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- TMEM161A | c.494del p.G165Vfs*39 | Frame Shift Del (DEL) | VAF 152/384 reads (40%) | called by mutect2, varscan2
- TMEM70 | c.440T>A p.I147N | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- TMIGD2 | c.518G>A p.W173* | Nonsense Mutation (SNP) | VAF 67/161 reads (42%) | called by muse, mutect2, varscan2
- TMIGD2 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TMPRSS9 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNIK | c.1888T>C p.S630P | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, varscan2
- TOMM40 | c.257G>A p.C86Y | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TOMM70 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 158/634 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOPBP1 | c.3334G>A p.A1112T | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIP11 | c.140-2A>G p.X47_splice | Splice Site (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- TSC2 | c.3814+2dup p.X1272_splice | Splice Site (INS) | VAF 209/663 reads (32%) | called by mutect2, pindel, varscan2
- TSEN15 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- TSHZ3 | c.2935A>G p.N979D | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TSPYL4 | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.86196del p.V28733Lfs*17 (on ENST00000591111; = p.V21309Lfs*17 on NM_003319.4) | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | called by mutect2, pindel, varscan2
- TTN | c.71495A>T p.E23832V (on ENST00000591111; = p.E16408V on NM_003319.4) | Missense Mutation (SNP) | VAF 34/122 reads (28%) | PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TUT4 | c.550del p.I184Ffs*11 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, varscan2
- TVP23B | c.220T>C p.C74R | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TXNDC16 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- UBE4A | c.1884dup p.A629Cfs*3 (on ENST00000252108 / NM_001204077.2; = p.A636Cfs*3 on NM_004788.4) | Frame Shift Ins (INS) | VAF 27/88 reads (31%) | called by mutect2, pindel, varscan2
- UCHL5 | c.45dup p.G16Rfs*8 | Frame Shift Ins (INS) | VAF 64/294 reads (22%) | called by mutect2, pindel, varscan2
- UGT1A3 | c.318dup p.L107Sfs*20 | Frame Shift Ins (INS) | VAF 32/112 reads (29%) | called by mutect2, pindel, varscan2
- UNC5A | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- UNC5C | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- UNC80 | c.7129T>C p.Y2377H | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- URI1 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VIM | c.1379A>G p.Q460R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, varscan2
- VIRMA | c.4142G>C p.R1381P | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDFY4 | c.4354A>G p.R1452G | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR19 | c.1474A>G p.T492A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- WDR5B | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- XPR1 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- YIF1B | c.737T>A p.I246N (on ENST00000339413 / NM_001039673.3; = p.I231N on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/372 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZCCHC14 | c.2546T>C p.V849A (on ENST00000268616; = p.V986A on NM_015144.3) | Missense Mutation (SNP) | VAF 138/366 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZFHX3 | c.6195dup p.A2066Rfs*90 | Frame Shift Ins (INS) | VAF 78/215 reads (36%) | called by mutect2, pindel, varscan2
- ZFP2 | c.839G>T p.S280I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ZHX1 | c.1358T>G p.V453G | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- ZMYND11 | c.1686+6T>C | Splice Region (SNP) | VAF 47/153 reads (31%) | called by muse, mutect2, varscan2
- ZNF143 | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ZNF174 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 116/289 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF205 | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- ZNF227 | c.1406G>A p.C469Y | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ZNF292 | c.2346G>A p.M782I | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZNF337 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF385B | c.758C>G p.S253* | Nonsense Mutation (SNP) | VAF 59/191 reads (31%) | called by muse, mutect2, varscan2
- ZNF469 | c.3875del p.P1292Lfs*235 (on ENST00000437464; = p.P1320Lfs*235 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 153/414 reads (37%) | called by mutect2, pindel, varscan2
- ZNF506 | c.345del p.G116Afs*5 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- ZNF554 | c.83A>G p.Q28R | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF579 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 70/198 reads (35%) | called by mutect2, varscan2
- ZNF688 | c.622dup p.E208Gfs*51 | Frame Shift Ins (INS) | VAF 31/104 reads (30%) | called by mutect2, pindel, varscan2
- ZNF691 | c.898C>A p.R300S (on ENST00000372502; = p.R269S on NM_015911.3) | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- ZNF843 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZP4 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 141/618 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACAD9 | c.546G>A p.E182= | Silent (SNP) | VAF 201/696 reads (29%) | called by muse, mutect2, varscan2
- ACTN1 | c.1033C>T p.L345= | Silent (SNP) | VAF 24/311 reads (8%) | called by muse, mutect2
- ADCY7 | c.1377G>A p.Q459= | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2
- ADORA1 | c.30C>T p.A10= | Silent (SNP) | VAF 63/243 reads (26%) | catalogued as rs978339398; called by muse, mutect2, varscan2
- AFF3 | c.2233C>T p.L745= | Silent (SNP) | VAF 115/374 reads (31%) | called by muse, mutect2, varscan2
- AGAP3 | c.2433C>T p.D811= (on ENST00000622464; = p.D847= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 169/387 reads (44%) | catalogued as rs544001543; called by muse, mutect2, varscan2
- AGAP9 | c.954C>T p.S318= | Silent (SNP) | VAF 181/1130 reads (16%) | called by muse, mutect2, varscan2
- AP2B1 | c.540C>T p.A180= | Silent (SNP) | VAF 76/168 reads (45%) | catalogued as rs746003974; called by muse, mutect2, varscan2
- ARHGEF26 | c.174G>A p.T58= | Silent (SNP) | VAF 62/225 reads (28%) | catalogued as COSV100726664; called by muse, mutect2, varscan2
- ARHGEF33 | c.1207C>T p.L403= | Silent (SNP) | VAF 34/127 reads (27%) | called by muse, mutect2, varscan2
- ARVCF | c.102G>T p.R34= | Silent (SNP) | VAF 249/600 reads (42%) | called by muse, mutect2, varscan2
- ATG10 | c.438C>T p.D146= | Silent (SNP) | VAF 24/73 reads (33%) | called by muse, varscan2
- ATG2A | c.972C>T p.A324= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as rs148409083; called by muse, mutect2, varscan2
- ATP13A1 | c.1413C>T p.S471= | Silent (SNP) | VAF 118/261 reads (45%) | called by muse, mutect2, varscan2
- ATP1A4 | c.2706T>C p.N902= | Silent (SNP) | VAF 58/247 reads (23%) | catalogued as rs775333227; called by muse, mutect2, varscan2
331 further variants in this file (0 protein-altering or splice-affecting, 196 silent, 135 other) are not listed here.
